Somatic mutation profile of tumor specimen C3N-02282-05 (aliquot CPT0125360006) from CPTAC case C3N-02282, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 63.6 years (23,227 days).
Specimen C3N-02282-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a626155-d155-4a9b-8c04-373369598268.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02282-31 (Blood Derived Normal), aliquot CPT0125400002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e32acd4-ef04-47eb-b435-7bec3297bc54

The open-access MAF lists 273 somatic variants for this specimen: 194 protein-altering or splice-affecting, 52 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 170, Silent 52, Nonsense Mutation 12, Intron 9, Frame Shift Del 8, RNA 7, 5'UTR 4, 5'Flank 4, In Frame Del 2, 3'UTR 2, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 87/371 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs104894228, CM060018, COSV54236651, COSV54236730, COSV54241641; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.581T>C p.L194P | Missense Mutation (SNP) | VAF 201/494 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519998, COSV52663681, COSV52677924, COSV52679257, COSV52713187; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCB1 | c.1899T>A p.N633K | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs1203228011; called by muse, mutect2, varscan2
- ABCB5 | c.730G>C p.A244P | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99328607; called by muse, mutect2, varscan2
- ACIN1 | c.697C>G p.Q233E | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.759); catalogued as rs758772215; called by muse, mutect2, varscan2
- ADGRD1 | c.1060A>G p.I354V | Missense Mutation (SNP) | VAF 136/328 reads (41%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs778501649; called by muse, mutect2, varscan2
- ANGPT4 | c.1427T>C p.M476T | Missense Mutation (SNP) | VAF 51/478 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as rs760787523; called by muse, mutect2
- ANKRD34C | c.665C>A p.T222N | Missense Mutation (SNP) | VAF 54/314 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV69854931; called by muse, mutect2, varscan2
- B4GALT1 | c.53C>G p.S18C | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.417); catalogued as rs904022093, COSV65707884; called by muse, mutect2
- CAMSAP3 | c.3498C>G p.S1166R | Missense Mutation (SNP) | VAF 47/244 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs746413780; called by muse, mutect2, varscan2
- CEP350 | c.9271G>A p.G3091R | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs542770010, COSV62603218; called by muse, mutect2, varscan2
- CLEC14A | c.1148C>A p.T383K | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100643697; called by muse, mutect2, varscan2
- CLTC | c.367A>T p.T123S | Missense Mutation (SNP) | VAF 70/366 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV52247043; called by muse, mutect2, varscan2
- CNGA4 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 51/216 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770277700, COSV66005755, COSV66006249; called by muse, mutect2, varscan2
- CNOT1 | c.2221G>A p.G741S | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1006271206; called by muse, mutect2, varscan2
- CNTRL | c.3151A>T p.R1051W | Missense Mutation (SNP) | VAF 68/148 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs1349738886; called by muse, mutect2, varscan2
- COL15A1 | c.1712G>T p.G571V | Missense Mutation (SNP) | VAF 71/211 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100897461; called by muse, mutect2, varscan2
- DKK2 | c.631G>T p.G211W | Missense Mutation (SNP) | VAF 71/421 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53397902; called by muse, mutect2, varscan2
- DNAAF5 | c.40C>T p.H14Y | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.029); catalogued as COSV52419525; called by muse, mutect2
- DNAH5 | c.8976G>A p.M2992I | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.05); catalogued as COSV54247879, COSV99447701; called by muse, mutect2
- EXOC3L4 | c.280G>A p.G94S | Missense Mutation (SNP) | VAF 161/488 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.041); catalogued as rs777125027, COSV66295442; called by muse, mutect2, varscan2
- FIG4 | c.1137G>T p.K379N | Missense Mutation (SNP) | VAF 135/520 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100019222; called by muse, mutect2, varscan2
- FPR1 | c.625G>A p.G209S | Missense Mutation (SNP) | VAF 60/407 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs991593657, COSV104395337; called by muse, mutect2, varscan2
- GABRR2 | c.505A>T p.S169C | Missense Mutation (SNP) | VAF 76/213 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV68764430; called by muse, mutect2, varscan2
- GAGE2A | c.139A>C p.T47P | Missense Mutation (SNP) | VAF 101/1049 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV62995884; called by muse, varscan2
- GPR148 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.934); catalogued as rs113110453, COSV59308130; called by muse, mutect2, varscan2
- GPR20 | c.235T>C p.C79R | Missense Mutation (SNP) | VAF 52/435 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV66683855; called by muse, mutect2, varscan2
- HERC1 | c.8638C>T p.H2880Y | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.069); catalogued as rs1242317085; called by muse, mutect2, varscan2
- HPRT1 | c.606G>C p.L202F | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.432); catalogued as CM043001; called by muse, mutect2
- IRX1 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 32/311 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as rs1433427448, COSV100116749, COSV57358467, COSV57362662; called by muse, mutect2, varscan2
- KCNK18 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 45/233 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs547078514; called by muse, mutect2, varscan2
- KIF4B | c.1303G>T p.E435* | Nonsense Mutation (SNP) | VAF 64/250 reads (26%) | catalogued as rs757833636; called by muse, mutect2, varscan2
- LRIT1 | c.794C>G p.S265C | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1253343742; called by muse, mutect2, varscan2
- LUZP4 | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 44/131 reads (34%) | catalogued as rs782503093, CM134624, COSV64218880; called by muse, mutect2, varscan2
- MADD | c.2480G>T p.R827L | Missense Mutation (SNP) | VAF 51/262 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.651); catalogued as COSV60630521; called by muse, mutect2, varscan2
- MORC1 | c.1990G>T p.V664F | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV51713824; called by muse, mutect2, varscan2
- MOXD1 | c.783C>G p.N261K | Missense Mutation (SNP) | VAF 119/305 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV60942993; called by muse, mutect2, varscan2
- MTERF2 | c.420C>G p.F140L | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs1211240908, COSV99526817; called by muse, mutect2, varscan2
- NAV3 | c.5297C>T p.A1766V | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.137); catalogued as rs768748970, COSV99890417, COSV99893896; called by muse, mutect2, varscan2
- OCA2 | c.1678C>T p.R560C | Missense Mutation (SNP) | VAF 140/802 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs147905292; called by muse, mutect2, varscan2
- OR4C16 | c.893A>T p.K298M | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.303); catalogued as rs747359591; called by muse, mutect2, varscan2
- OR8D4 | c.864G>C p.L288F | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.26); catalogued as COSV58430813; called by mutect2, varscan2
- PCDHB9 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.952); catalogued as COSV53379758; called by muse, mutect2, varscan2
- PFDN6 | c.160A>C p.N54H | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV65841867; called by muse, mutect2, varscan2
- PHACTR1 | c.749C>G p.P250R | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100277567; called by muse, mutect2, varscan2
- PRDM14 | c.636C>A p.S212R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.307); catalogued as COSV99400442; called by mutect2, varscan2
- PRX | c.259G>T p.A87S | Missense Mutation (SNP) | VAF 119/610 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as rs1274747511; called by muse, mutect2, varscan2
- RASAL1 | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.07); catalogued as COSV55656190; called by muse, mutect2
- RBBP6 | c.3899A>T p.N1300I | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.881); catalogued as COSV60504301; called by muse, mutect2
- RPS6KC1 | c.1229del p.G410Afs*11 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | catalogued as COSV100873784, COSV65297070; called by mutect2, pindel, varscan2
- RYR2 | c.4469C>A p.A1490E | Missense Mutation (SNP) | VAF 52/340 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV63679382, COSV63702770; called by muse, mutect2, varscan2
- SCN2A | c.1728C>A p.S576R | Missense Mutation (SNP) | VAF 73/185 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1382196994, COSV51851119; called by muse, mutect2, varscan2
- SLC45A4 | c.332G>T p.R111L (on ENST00000517878 / NM_001286646.2; = p.R60L on NM_001080431.2) | Missense Mutation (SNP) | VAF 75/367 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV50144967; called by muse, mutect2, varscan2
- SLIT2 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.149); catalogued as rs957379784; called by muse, mutect2
- SMARCA4 | c.3013C>T p.R1005* | Nonsense Mutation (SNP) | VAF 163/593 reads (27%) | catalogued as CM144584, COSV60786701; called by muse, mutect2, varscan2
- STXBP1 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 14/438 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.309); catalogued as COSV64815786; called by muse, mutect2
- TCN2 | c.64G>T p.E22* | Nonsense Mutation (SNP) | VAF 30/162 reads (19%) | catalogued as COSV53191627; called by muse, mutect2
- TET2 | c.2578C>T p.Q860* | Nonsense Mutation (SNP) | VAF 14/448 reads (3%) | catalogued as COSV54397976; called by muse, mutect2
- THRB | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 60/464 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.713); catalogued as rs1263847441; called by muse, mutect2, varscan2
- TRIM43B | c.638A>G p.Q213R | Missense Mutation (SNP) | VAF 38/246 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV71433276; called by mutect2, varscan2
- URGCP | c.2789G>T p.R930L (on ENST00000453200 / NM_001077663.3; = p.R921L on NM_017920.4) | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV56247847; called by muse, mutect2, varscan2
- USP22 | c.848A>G p.N283S | Missense Mutation (SNP) | VAF 107/225 reads (48%) | SIFT tolerated (0.83); PolyPhen benign (0.012); catalogued as rs201217885; called by muse, mutect2, varscan2
- YIPF7 | c.637C>G p.P213A | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1229277926, COSV60658191; called by muse, mutect2, varscan2
- ZDHHC2 | c.776G>A p.G259E | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100025027, COSV50497353; called by muse, mutect2, varscan2
- ZSWIM9 | c.945G>C p.Q315H | Missense Mutation (SNP) | VAF 38/234 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.937); catalogued as rs1312392269; called by muse, mutect2, varscan2
- ADCY10 | c.4379A>C p.Y1460S | Missense Mutation (SNP) | VAF 65/347 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AGAP2 | c.898A>G p.S300G | Missense Mutation (SNP) | VAF 63/538 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGBL1 | c.1714G>T p.V572F | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- AKAP9 | c.1239G>T p.Q413H | Missense Mutation (SNP) | VAF 92/370 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- AKR1B15 | c.400G>T p.D134Y | Missense Mutation (SNP) | VAF 33/258 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ALMS1 | c.4599C>A p.F1533L | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- ANO10 | c.1643C>G p.P548R | Missense Mutation (SNP) | VAF 104/238 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- ANO5 | c.1333G>T p.E445* | Nonsense Mutation (SNP) | VAF 60/322 reads (19%) | called by muse, mutect2, varscan2
- ANTXRL | c.966-1G>C p.X322_splice | Splice Site (SNP) | VAF 44/198 reads (22%) | called by muse, mutect2, varscan2
- AOX1 | c.2032G>T p.V678L | Missense Mutation (SNP) | VAF 11/281 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.633); called by muse, mutect2
- APEH | c.1556T>A p.M519K | Missense Mutation (SNP) | VAF 65/314 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- APEH | c.1557G>T p.M519I | Missense Mutation (SNP) | VAF 63/311 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARHGAP9 | c.791A>G p.K264R | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.38); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ARHGEF2 | c.2591G>T p.G864V (on ENST00000361247 / NM_001162383.2; = p.G836V on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- ATG2B | c.3322A>G p.I1108V | Missense Mutation (SNP) | VAF 74/180 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- BAIAP2L1 | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 7/108 reads (6%) | called by muse, mutect2
- BARD1 | c.1594G>T p.D532Y | Missense Mutation (SNP) | VAF 68/343 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BAZ2A | c.580C>G p.P194A | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- BBS10 | c.845A>T p.Q282L | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- BDH2 | c.226G>C p.D76H | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- BEND6 | c.364G>T p.G122W | Missense Mutation (SNP) | VAF 19/223 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- BHMG1 | c.255G>T p.L85F | Missense Mutation (SNP) | VAF 38/213 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BLZF1 | c.808G>C p.E270Q | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CABIN1 | c.4832del p.K1611Rfs*13 | Frame Shift Del (DEL) | VAF 186/756 reads (25%) | called by mutect2, pindel, varscan2
- CASKIN1 | c.1984_2008del p.Q662Rfs*34 | Frame Shift Del (DEL) | VAF 70/398 reads (18%) | called by mutect2, pindel
- CATSPERB | c.2506C>T p.H836Y | Missense Mutation (SNP) | VAF 85/247 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CCDC151 | c.1083G>C p.K361N | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- CDH10 | c.733C>A p.Q245K | Missense Mutation (SNP) | VAF 62/398 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- CDH8 | c.1989C>G p.N663K | Missense Mutation (SNP) | VAF 87/242 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP46 | c.4856G>T p.R1619L | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- CNOT1 | c.2220G>T p.L740F | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CNTN1 | c.1473del p.A493Lfs*54 | Frame Shift Del (DEL) | VAF 32/224 reads (14%) | called by mutect2, varscan2
- CROCC | c.1558A>T p.T520S | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- DCUN1D3 | c.861del p.R288Efs*65 | Frame Shift Del (DEL) | VAF 20/144 reads (14%) | called by mutect2, pindel
- DDX60 | c.5045C>T p.S1682F | Missense Mutation (SNP) | VAF 14/177 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.127); called by muse, mutect2
- DDX60L | c.1870G>T p.V624F | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- DNAH5 | c.8977G>T p.E2993* | Nonsense Mutation (SNP) | VAF 26/254 reads (10%) | called by muse, mutect2
- DNAH7 | c.8312del p.N2771Ifs*28 | Frame Shift Del (DEL) | VAF 15/132 reads (11%) | called by mutect2, pindel, varscan2
- E2F4 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 51/183 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- EYS | c.2986T>A p.Y996N | Missense Mutation (SNP) | VAF 13/169 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.304); called by muse, mutect2
- F10 | c.346T>A p.F116I | Missense Mutation (SNP) | VAF 34/623 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2
- FANCB | c.1087G>T p.G363* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2
- FBXL13 | c.875C>G p.P292R | Missense Mutation (SNP) | VAF 86/244 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- FCGBP | c.5794G>T p.A1932S | Missense Mutation (SNP) | VAF 19/502 reads (4%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.813); called by muse, mutect2
- FRG2C | c.590A>T p.Q197L | Missense Mutation (SNP) | VAF 42/622 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.888); called by muse, mutect2
- FSHB | c.284C>A p.P95Q | Missense Mutation (SNP) | VAF 77/448 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GCSAML | c.373C>G p.H125D | Missense Mutation (SNP) | VAF 40/209 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- GON4L | c.3888G>C p.E1296D | Missense Mutation (SNP) | VAF 173/901 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- GPR156 | c.2309C>T p.S770F | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- GPR158 | c.822C>A p.N274K | Missense Mutation (SNP) | VAF 54/219 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- GUCY1A1 | c.512A>G p.K171R | Missense Mutation (SNP) | VAF 38/295 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- IFNA7 | c.381dup p.G128Wfs*10 | Frame Shift Ins (INS) | VAF 77/388 reads (20%) | called by mutect2, pindel, varscan2
- IGLV1-36 | c.64G>T p.V22L | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- IPO5 | c.2350T>G p.C784G | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.188); called by mutect2, varscan2
- KCNT2 | c.1374T>G p.I458M | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- KIAA0408 | c.308A>C p.K103T | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- KIF18A | c.1658G>A p.R553K | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF1B | c.112A>T p.I38F | Missense Mutation (SNP) | VAF 48/249 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- KNDC1 | c.3418A>G p.R1140G | Missense Mutation (SNP) | VAF 39/228 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- LHCGR | c.686T>A p.I229N | Missense Mutation (SNP) | VAF 68/396 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- MAP3K10 | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MARCHF1 | c.494C>A p.A165E (on ENST00000274056; = p.A148E on NM_017923.4) | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MCTP1 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 60/180 reads (33%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- MTMR10 | c.46C>A p.L16M | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.723); called by muse, varscan2
- MUC19 | c.848T>C p.I283T | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- MYH10 | c.2596G>C p.E866Q | Missense Mutation (SNP) | VAF 25/418 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2
- MYOM1 | c.3353T>C p.I1118T | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MYPN | c.1737G>T p.E579D | Missense Mutation (SNP) | VAF 55/297 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MYPN | c.3773C>T p.T1258I | Missense Mutation (SNP) | VAF 71/511 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYT1L | c.400G>T p.E134* | Nonsense Mutation (SNP) | VAF 45/209 reads (22%) | called by muse, mutect2, varscan2
- MYT1L | c.399G>T p.E133D | Missense Mutation (SNP) | VAF 44/210 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NALCN | c.3644C>T p.T1215I | Missense Mutation (SNP) | VAF 44/195 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NOTCH1 | c.2733C>A p.C911* | Nonsense Mutation (SNP) | VAF 286/667 reads (43%) | called by muse, mutect2, varscan2
- OR10G2 | c.838T>A p.F280I | Missense Mutation (SNP) | VAF 36/216 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, varscan2
- OR10S1 | c.640C>G p.L214V | Missense Mutation (SNP) | VAF 42/228 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- OR5AP2 | c.377A>G p.Y126C | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCCA | c.1221G>T p.K407N | Missense Mutation (SNP) | VAF 50/345 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- PDE4DIP | c.1625G>C p.R542T | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by mutect2, varscan2
- PDE6A | c.463A>G p.N155D | Missense Mutation (SNP) | VAF 54/172 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PHKG1 | c.443A>T p.H148L | Missense Mutation (SNP) | VAF 41/240 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PHLDB2 | c.2974C>G p.P992A (on ENST00000393925 / NM_001134439.2; = p.P949A on NM_145753.2) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- PIK3CG | c.1670C>G p.A557G | Missense Mutation (SNP) | VAF 99/269 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PKD2L1 | c.845C>A p.A282E | Missense Mutation (SNP) | VAF 76/433 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PRAMEF27 | c.1367G>C p.C456S | Missense Mutation (SNP) | VAF 192/612 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PRR13 | c.395A>G p.H132R | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.005); called by muse, mutect2
- PRRT4 | c.2662_2668del p.D888* | Frame Shift Del (DEL) | VAF 52/454 reads (11%) | called by mutect2, pindel, varscan2
- PTPRZ1 | c.4335C>G p.C1445W | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- RARG | c.779T>C p.I260T | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RASGEF1A | c.184G>C p.D62H | Missense Mutation (SNP) | VAF 40/220 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RASSF1 | c.362C>A p.T121K (on ENST00000357043 / NM_170714.2; = p.T117K on NM_007182.5) | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- REV1 | c.2394G>T p.K798N | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- RFX4 | c.1346G>T p.S449I (on ENST00000392842 / NM_213594.3; = p.S355I on NM_032491.6) | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- RGPD4 | c.2118A>C p.E706D | Missense Mutation (SNP) | VAF 40/256 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ROCK1 | c.725C>A p.S242Y | Missense Mutation (SNP) | VAF 32/190 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RRBP1 | c.1728A>T p.E576D | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2
- RYR2 | c.9989C>T p.A3330V | Missense Mutation (SNP) | VAF 31/237 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- SBNO2 | c.4008_4013del p.A1339_G1340del | In Frame Del (DEL) | VAF 50/271 reads (18%) | called by mutect2, pindel, varscan2
- SCN10A | c.974G>T p.C325F | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEC14L5 | c.241G>C p.V81L | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.023); called by muse, varscan2
- SEMA4A | c.481_501del p.L161_D167del | In Frame Del (DEL) | VAF 33/403 reads (8%) | called by mutect2, pindel
- SERPINA11 | c.707A>G p.E236G | Missense Mutation (SNP) | VAF 48/254 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- SIGLEC7 | c.55_74del p.Q19Lfs*32 | Frame Shift Del (DEL) | VAF 45/271 reads (17%) | called by mutect2, varscan2
- SIPA1L3 | c.4077G>T p.R1359S | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SLC2A5 | c.563A>T p.N188I | Missense Mutation (SNP) | VAF 36/296 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- SLC30A8 | c.388A>T p.K130* | Nonsense Mutation (SNP) | VAF 16/66 reads (24%) | called by muse, mutect2
- SOWAHB | c.448G>A p.G150S | Missense Mutation (SNP) | VAF 18/505 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2
- SPEF2 | c.2093A>T p.K698M | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- STARD3 | c.830C>A p.P277H | Missense Mutation (SNP) | VAF 94/290 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TFEC | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM229A | c.815C>A p.T272N | Missense Mutation (SNP) | VAF 71/356 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- TMEM63C | c.250G>T p.G84W | Missense Mutation (SNP) | VAF 53/264 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- TMEM88 | c.346C>A p.R116S | Missense Mutation (SNP) | VAF 24/592 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.763); called by muse, mutect2
- TREH | c.1054T>G p.F352V | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- TRIP11 | c.5150T>A p.I1717K | Missense Mutation (SNP) | VAF 72/227 reads (32%) | SIFT tolerated (0.94); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTLL6 | c.1742C>A p.A581D (on ENST00000393382 / NM_001130918.3; = p.A274D on NM_173623.3) | Missense Mutation (SNP) | VAF 55/201 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- TTN | c.77618T>A p.V25873D (on ENST00000591111; = p.V18449D on NM_003319.4) | Missense Mutation (SNP) | VAF 93/230 reads (40%) | PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- UBR2 | c.3531G>T p.W1177C | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USH1C | c.1124A>T p.E375V | Missense Mutation (SNP) | VAF 118/518 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- USP34 | c.5595G>C p.W1865C | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- VEGFC | c.935G>T p.R312I | Missense Mutation (SNP) | VAF 74/217 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- VIRMA | c.85G>A p.V29I | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- VWA5B1 | c.1508G>T p.G503V | Missense Mutation (SNP) | VAF 36/211 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- XKR7 | c.1556A>T p.E519V | Missense Mutation (SNP) | VAF 55/273 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ZMAT3 | c.599G>C p.G200A | Missense Mutation (SNP) | VAF 36/268 reads (13%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF100 | c.1106G>C p.G369A | Missense Mutation (SNP) | VAF 62/338 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- ZNF469 | c.1456C>A p.Q486K | Missense Mutation (SNP) | VAF 64/155 reads (41%) | SIFT tolerated (0.89); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- ZNF528 | c.581T>A p.V194D | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- ZNF804B | c.1597T>C p.Y533H | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- ZP1 | c.1776C>A p.D592E | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- AKAP9 | c.10848T>C p.N3616= (on ENST00000359028; = p.N3592= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 70/318 reads (22%) | called by muse, mutect2, varscan2
- AL139011.2 | c.543A>T p.S181= | Silent (SNP) | VAF 18/62 reads (29%) | called by muse, mutect2, varscan2
- ALK | c.633C>A p.S211= | Silent (SNP) | VAF 75/211 reads (36%) | called by muse, mutect2, varscan2
- ART5 | c.465G>A p.G155= | Silent (SNP) | VAF 42/164 reads (26%) | called by muse, mutect2, varscan2
- BPTF | c.8274C>G p.L2758= | Silent (SNP) | VAF 80/183 reads (44%) | called by muse, mutect2, varscan2
- CD163 | c.1248T>C p.C416= | Silent (SNP) | VAF 127/744 reads (17%) | catalogued as rs1245816661; called by muse, mutect2, varscan2
- CD5L | c.780G>T p.L260= | Silent (SNP) | VAF 40/167 reads (24%) | called by muse, mutect2, varscan2
- CHST1 | c.999G>A p.Q333= | Silent (SNP) | VAF 62/280 reads (22%) | called by muse, mutect2, varscan2
- CNTN1 | c.3039T>G p.L1013= | Silent (SNP) | VAF 100/499 reads (20%) | called by muse, mutect2, varscan2
- CPNE8 | c.378A>T p.S126= | Silent (SNP) | VAF 21/180 reads (12%) | called by muse, mutect2, varscan2
- DISP1 | c.4290G>T p.G1430= | Silent (SNP) | VAF 73/357 reads (20%) | called by muse, mutect2, varscan2
- ELOA2 | c.2142G>C p.L714= | Silent (SNP) | VAF 123/648 reads (19%) | catalogued as COSV55296047; called by muse, mutect2, varscan2
- EP400 | c.4368C>T p.T1456= | Silent (SNP) | VAF 57/147 reads (39%) | called by muse, mutect2, varscan2
- FAM71E2 | c.1854G>A p.K618= | Silent (SNP) | VAF 40/267 reads (15%) | called by muse, mutect2, varscan2
- FANCA | c.4344G>C p.L1448= | Silent (SNP) | VAF 89/733 reads (12%) | called by muse, mutect2, varscan2
- FHL5 | c.732G>A p.Q244= | Silent (SNP) | VAF 38/102 reads (37%) | called by muse, mutect2
- GORASP1 | c.1209C>A p.S403= | Silent (SNP) | VAF 196/403 reads (49%) | called by muse, mutect2, varscan2
- HEATR6 | c.2505A>G p.S835= | Silent (SNP) | VAF 144/375 reads (38%) | called by muse, mutect2, varscan2
- KIR3DL2 | c.543C>G p.S181= | Silent (SNP) | VAF 165/1033 reads (16%) | called by muse, mutect2, varscan2
- LRRC38 | c.129C>A p.R43= | Silent (SNP) | VAF 15/98 reads (15%) | called by muse, mutect2, varscan2
- MALT1 | c.414C>G p.V138= | Silent (SNP) | VAF 9/158 reads (6%) | called by muse, mutect2
- MOXD1 | c.198C>A p.P66= | Silent (SNP) | VAF 165/412 reads (40%) | called by muse, mutect2, varscan2
- MYO1E | c.2202A>G p.R734= | Silent (SNP) | VAF 40/244 reads (16%) | called by muse, mutect2, varscan2
- NRXN3 | c.981G>T p.P327= (on ENST00000557594 / NM_001272020.2; = p.P959= on NM_004796.6) | Silent (SNP) | VAF 55/168 reads (33%) | called by muse, mutect2, varscan2
- NWD2 | c.294C>A p.L98= | Silent (SNP) | VAF 10/235 reads (4%) | called by muse, mutect2
- OR1A1 | c.369T>A p.A123= | Silent (SNP) | VAF 68/289 reads (24%) | called by muse, mutect2, varscan2
- OR4M1 | c.480G>T p.V160= | Silent (SNP) | VAF 68/422 reads (16%) | called by muse, mutect2, varscan2
- OR4N5 | c.207G>A p.L69= | Silent (SNP) | VAF 19/141 reads (13%) | catalogued as rs111858769, COSV61320741; called by muse, mutect2, varscan2
- OR5B21 | c.309G>T p.V103= | Silent (SNP) | VAF 61/322 reads (19%) | catalogued as rs1270458928, COSV100835185; called by muse, mutect2, varscan2
- PCDHB8 | c.189G>C p.R63= | Silent (SNP) | VAF 40/422 reads (9%) | catalogued as rs1165825499; called by muse, mutect2, varscan2
- PPP1R13L | c.1998C>T p.N666= | Silent (SNP) | VAF 44/305 reads (14%) | catalogued as rs1405572289; called by muse, mutect2, varscan2
- PRKCH | c.2041T>C p.L681= | Silent (SNP) | VAF 11/101 reads (11%) | catalogued as rs527487305; called by muse, mutect2, varscan2
- PTPRT | c.2284C>T p.L762= | Silent (SNP) | VAF 49/231 reads (21%) | catalogued as rs781138141, COSV62030226; called by muse, mutect2, varscan2
- RAB8B | c.168A>G p.K56= | Silent (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- RHBDF1 | c.573C>T p.S191= | Silent (SNP) | VAF 78/303 reads (26%) | catalogued as rs1473621997; called by muse, mutect2, varscan2
- ROBO2 | c.3220C>T p.L1074= | Silent (SNP) | VAF 35/112 reads (31%) | catalogued as rs143136849, COSV59923121; called by muse, mutect2, varscan2
- RTTN | c.6276A>G p.Q2092= | Silent (SNP) | VAF 18/234 reads (8%) | called by muse, mutect2
- SFXN1 | c.270A>T p.I90= | Silent (SNP) | VAF 30/93 reads (32%) | called by muse, mutect2, varscan2
- SLC12A5 | c.1204C>T p.L402= (on ENST00000454036 / NM_001134771.2; = p.L379= on NM_020708.5) | Silent (SNP) | VAF 120/406 reads (30%) | catalogued as COSV54794865; called by muse, mutect2, varscan2
- SLC30A8 | c.390G>A p.K130= | Silent (SNP) | VAF 16/64 reads (25%) | called by muse, mutect2
- SLC5A5 | c.1599C>A p.A533= | Silent (SNP) | VAF 126/488 reads (26%) | called by muse, mutect2, varscan2
- SPATA31A1 | c.2500T>C p.L834= | Silent (SNP) | VAF 15/138 reads (11%) | called by mutect2, varscan2
- SYMPK | c.1956C>T p.G652= | Silent (SNP) | VAF 62/316 reads (20%) | catalogued as rs1568612951; called by muse, mutect2, varscan2
- TECPR1 | c.294G>T p.V98= | Silent (SNP) | VAF 90/522 reads (17%) | called by muse, mutect2, varscan2
- TNRC18 | c.3639C>T p.C1213= | Silent (SNP) | VAF 40/502 reads (8%) | catalogued as rs541700079, COSV68165205; called by muse, mutect2
- TRIM68 | c.756G>A p.S252= | Silent (SNP) | VAF 61/318 reads (19%) | catalogued as rs201878459; called by muse, mutect2, varscan2
- TTC7A | c.729C>T p.A243= | Silent (SNP) | VAF 43/168 reads (26%) | catalogued as rs759278466; called by muse, mutect2, varscan2
- USH2A | c.5373G>A p.L1791= | Silent (SNP) | VAF 36/189 reads (19%) | catalogued as COSV100236736; called by muse, mutect2, varscan2
- UTRN | c.9645C>T p.S3215= | Silent (SNP) | VAF 121/307 reads (39%) | called by muse, mutect2, varscan2
- VN1R5 | c.591T>C p.S197= | Silent (SNP) | VAF 25/114 reads (22%) | called by muse, mutect2, varscan2
- VWA3A | c.2037A>C p.A679= | Silent (SNP) | VAF 56/271 reads (21%) | called by muse, mutect2, varscan2
- ZNF25 | c.744T>C p.H248= | Silent (SNP) | VAF 21/144 reads (15%) | called by muse, mutect2, varscan2
- AC073310.1 | n.293C>A | RNA (SNP) | VAF 39/278 reads (14%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73824376 del A | 5'Flank (DEL) | VAF 34/115 reads (30%) | called by mutect2, pindel, varscan2
- AL353804.4 | chrX:73825092 C>T | 5'Flank (SNP) | VAF 44/123 reads (36%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505530 G>T | 5'Flank (SNP) | VAF 15/61 reads (25%) | called by muse, mutect2, varscan2
- CFAP94 | c.3+44G>C | Intron (SNP) | VAF 114/611 reads (19%) | called by muse, mutect2, varscan2
- COLEC11 | c.-26-708G>T | Intron (SNP) | VAF 58/160 reads (36%) | called by muse, mutect2, varscan2
- FADS2 | chr11:61826357 C>T | 5'Flank (SNP) | VAF 72/376 reads (19%) | called by muse, mutect2
- FLT4 | c.3808-48G>A | Intron (SNP) | VAF 74/246 reads (30%) | catalogued as rs142426150; called by muse, mutect2, varscan2
- ITGB1BP1 | c.-36+74C>G | Intron (SNP) | VAF 43/198 reads (22%) | called by muse, mutect2, varscan2
- LINC00174 | n.3769G>A | RNA (SNP) | VAF 80/313 reads (26%) | catalogued as rs781369919; called by muse, mutect2, varscan2
- LINC00868 | n.634_641delinsT | RNA (DEL) | VAF 98/414 reads (24%) | called by pindel, varscan2*
- OR2W5 | n.515T>A | RNA (SNP) | VAF 105/533 reads (20%) | called by muse, mutect2, varscan2
- PACRG | c.613+102253G>C | Intron (SNP) | VAF 14/192 reads (7%) | called by muse, mutect2
- PRPF3 | c.1283-32T>G | Intron (SNP) | VAF 9/151 reads (6%) | called by muse, mutect2
- PTPRH | c.-32_-10del | 5'UTR (DEL) | VAF 28/172 reads (16%) | called by mutect2, pindel
- RHOBTB2 | c.-455G>A | 5'UTR (SNP) | VAF 32/170 reads (19%) | called by muse, mutect2, varscan2
- SGK2 | c.1120-1571A>G | Intron (SNP) | VAF 20/151 reads (13%) | catalogued as rs144536670; called by muse, mutect2, varscan2
- SSPOP | n.2770G>T | RNA (SNP) | VAF 59/160 reads (37%) | catalogued as COSV50487739; called by muse, mutect2, varscan2
- SSPOP | n.11504A>C | RNA (SNP) | VAF 88/621 reads (14%) | called by muse, mutect2, varscan2
- SYNE1 | c.*49G>T | 3'UTR (SNP) | VAF 12/186 reads (6%) | called by muse, mutect2
- TMEM198 | c.-94C>A | 5'UTR (SNP) | VAF 60/351 reads (17%) | called by muse, mutect2, varscan2
- TMEM236 | c.*2078C>A | 3'UTR (SNP) | VAF 36/412 reads (9%) | called by muse, mutect2
- TUBB8P7 | n.877G>T | RNA (SNP) | VAF 44/235 reads (19%) | catalogued as rs1385427112; called by muse, mutect2, varscan2
- TVP23C | c.462+7631G>T | Intron (SNP) | VAF 40/116 reads (34%) | called by muse, mutect2, varscan2
- UTS2 | chr1:7846755 G>C | 3'Flank (SNP) | VAF 27/152 reads (18%) | called by muse, mutect2, varscan2
- ZFHX4 | c.3325+3740T>C | Intron (SNP) | VAF 23/120 reads (19%) | called by muse, mutect2, varscan2
- ZNF749 | c.-7C>G | 5'UTR (SNP) | VAF 41/303 reads (14%) | called by muse, mutect2, varscan2
